Somatic mutation profile of tumor specimen TARGET-40-PATEEM-01A (aliquot TARGET-40-PATEEM-01A-01Y) from TARGET case TARGET-40-PATEEM, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 16.1 years (5,875 days).
Specimen TARGET-40-PATEEM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d54d047-d484-4f53-83dd-4995ca45e6b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PATEEM-10A (Blood Derived Normal), aliquot TARGET-40-PATEEM-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6ce95f6-5896-4c5d-a196-500339211dbb

The open-access MAF lists 71 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Intron 8, Nonsense Mutation 5, 3'UTR 4, 3'Flank 2, Splice Site 2, RNA 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.1324G>C p.A442P | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV60937697; called by muse, mutect2, varscan2
- DNAH17 | c.9719G>A p.G3240D | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101101376; called by muse, mutect2
- DNAI4 | c.1331C>A p.A444E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs930977596; called by muse, mutect2, varscan2
- FCGBP | c.5305G>A p.D1769N | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs1176023971; called by muse, varscan2
- FREM1 | c.4164G>C p.K1388N | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV66519231; called by muse, mutect2, varscan2
- HIP1 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as rs1554500994; called by muse, mutect2
- IGLV5-45 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as rs1374000201; called by muse, mutect2, varscan2
- INPP5D | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748315737, COSV64035937; called by muse, mutect2, varscan2
- KRT77 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs200529529; called by muse, mutect2, varscan2
- LDB2 | c.595T>G p.F199V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.403); catalogued as COSV100453946; called by muse, mutect2, varscan2
- MYO1F | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.721); catalogued as rs770457876; called by muse, varscan2
- PTPN14 | c.2994G>A p.W998* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as rs1238492148; called by muse, mutect2, varscan2
- REXO4 | c.910+1G>A p.X304_splice | Splice Site (SNP) | VAF 6/124 reads (5%) | catalogued as rs1205420168; called by muse, mutect2
- SNX6 | c.142A>G p.I48V (on ENST00000652385; = p.I36V on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs769251876; called by muse, mutect2, varscan2
- SRPX | c.677dup p.G227Rfs*17 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs1470216799; called by pindel, varscan2
- TMEM63C | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs775465673; called by muse, mutect2, varscan2
- TRMT2B | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV100105561; called by muse, mutect2, varscan2
- ABCB11 | c.2660C>T p.T887I | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- ADAM12 | c.2467C>T p.H823Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ADCY10 | c.1838T>A p.M613K | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- AEBP2 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- AL645922.1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- ARAP3 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- ARHGEF11 | c.3568G>T p.G1190C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ASNS | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ATP13A3 | c.2155T>G p.L719V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- CD33 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CYP2S1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 23/169 reads (14%) | called by muse, mutect2, varscan2
- DCLRE1B | c.445T>A p.C149S | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ENTPD4 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- FOCAD | c.4564C>T p.P1522S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LILRA2 | c.1432C>G p.Q478E (on ENST00000391738 / NM_001130917.3; = p.Q461E on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.287); called by muse, mutect2
- MAST4 | c.1775C>T p.S592F (on ENST00000403625 / NM_001164664.2; = p.S403F on NM_015183.3) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by mutect2, varscan2
- MYO1E | c.1229A>G p.E410G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PATJ | c.2246C>G p.S749* | Nonsense Mutation (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- PRRC2B | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- PYGO2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- SETD1A | c.3806C>T p.P1269L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLIT1 | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 76/269 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- STAG1 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- TANC1 | c.946+1G>A p.X316_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- TMEM132B | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRANK1 | c.4363G>A p.V1455I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- UNC79 | c.7279G>A p.A2427T (on ENST00000393151 / NM_001346218.2; = p.A2250T on NM_020818.5) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by mutect2, varscan2
- ACSBG2 | c.411C>G p.A137= | Silent (SNP) | VAF 14/110 reads (13%) | called by muse, varscan2
- ANO1 | c.573G>A p.L191= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs754852641, COSV60282014; called by muse, mutect2, varscan2
- FBXL18 | c.2022G>A p.A674= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs757464102, COSV66667634; called by muse, mutect2, varscan2
- MCM7 | c.1692C>T p.A564= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs540136580; called by muse, mutect2, varscan2
- PCNT | c.2541G>A p.Q847= | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- PNPLA4 | c.78C>T p.C26= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- RIC1 | c.2412G>A p.R804= | Silent (SNP) | VAF 45/168 reads (27%) | called by muse, mutect2, varscan2
- RIC1 | c.4041G>A p.E1347= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- RPL10A | c.627C>T p.T209= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs1388728039; called by muse, mutect2, varscan2
- SOHLH2 | c.672G>A p.L224= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- ZNF345 | c.540G>A p.G180= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- ALDH3A1 | c.*135C>T | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- ANKRD28 | c.1101-84_1101-77del | Intron (DEL) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- C7orf65 | n.28G>A | RNA (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- CEP41 | c.277+60C>T | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2
- CSHL1 | c.471+50G>A | Intron (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- CYP2C9 | c.*35C>T | 3'UTR (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- HK1 | c.*39C>T | 3'UTR (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100067815; called by muse, mutect2, varscan2
- LRRC28 | c.168+2802A>G | Intron (SNP) | VAF 47/121 reads (39%) | called by muse, mutect2, varscan2
- MGST3 | c.-7-67C>T | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- MYLK2 | c.*89T>A | 3'UTR (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- NNAT | chr20:37521212 C>T | 5'Flank (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- OR2T2 | chr1:248453899 G>T | 3'Flank (SNP) | VAF 7/34 reads (21%) | called by muse, varscan2
- RNF220 | c.907-50G>A | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- RPL3 | c.688+124A>T | Intron (SNP) | VAF 4/52 reads (8%) | catalogued as COSV53364619; called by muse, mutect2
- SMCO2 | c.601-129G>A | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- VRK3 | chr19:49971976 C>T | 3'Flank (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
